Somatic mutation profile of tumor specimen ALCH-B1V0-TTP1-A (aliquot ALCH-B1V0-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1V0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.2 years (29,645 days).
Specimen ALCH-B1V0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1214d8ee-c30a-4749-aea0-ebf4b1189971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1V0-NB1-A (Blood Derived Normal), aliquot ALCH-B1V0-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62069e12-9d11-4fc5-b55f-6a1b33404c95

The open-access MAF lists 217 somatic variants for this specimen: 147 protein-altering or splice-affecting, 45 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 45, Intron 13, Nonsense Mutation 12, 5'UTR 7, 3'UTR 4, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.1357G>T p.V453L (on ENST00000506720 / NM_001322402.2; = p.V385L on NM_015236.6) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.085); catalogued as COSV72265533; called by muse, mutect2, varscan2
- ANK2 | c.10903G>C p.E3635Q | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.204); catalogued as rs763711118; called by muse, mutect2, varscan2
- ANKRD44 | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV56556889; called by muse, mutect2, varscan2
- B4GALT5 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV65492494; called by muse, mutect2, varscan2
- C12orf40 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as rs1363789214, COSV61136125; called by muse, mutect2
- CCNA1 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs143100244; called by muse, mutect2
- CDH18 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 42/386 reads (11%) | catalogued as COSV56937489; called by muse, mutect2, varscan2
- CEP126 | c.2550G>C p.L850F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as rs1442961968; called by muse, mutect2
- CES1 | c.1108G>T p.E370* (on ENST00000361503 / NM_001025194.2; = p.E369* on NM_001266.5) | Nonsense Mutation (SNP) | VAF 102/631 reads (16%) | catalogued as rs185780477, COSV100828576; called by muse, mutect2, varscan2
- CSMD2 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV53945546; called by muse, mutect2, varscan2
- ESPL1 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV99229875; called by muse, mutect2
- FAM20A | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1012688874; called by muse, mutect2
- FLG | c.1759C>A p.R587S | Missense Mutation (SNP) | VAF 93/562 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.942); catalogued as COSV64247081; called by muse, mutect2, varscan2
- FLT3 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1235103983, COSV99609561; called by muse, mutect2
- FRAS1 | c.7354G>A p.E2452K | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs906024365; called by muse, mutect2
- IL12A | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV59758995, COSV59760382; called by muse, mutect2
- IL17RC | c.2221C>T p.R741C (on ENST00000295981 / NM_153461.4; = p.R655C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1477967348; called by muse, mutect2
- IRS1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs1024227751, COSV59333264, COSV59334285; called by muse, mutect2
- KCNAB2 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99378872; called by muse, mutect2, varscan2
- KCNH7 | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 36/238 reads (15%) | catalogued as COSV59798472; called by muse, mutect2, varscan2
- KLHL25 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV100563722; called by muse, mutect2
- LPO | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs1166759699; called by muse, mutect2
- LRRC4C | c.544T>A p.L182M | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV53422111; called by muse, mutect2
- MGAM | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV101516427; called by muse, mutect2
- NF1 | c.6208G>A p.E2070K (on ENST00000358273 / NM_001042492.3; = p.E2049K on NM_000267.3) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100647191; called by muse, varscan2
- NF1 | c.6283G>C p.D2095H (on ENST00000358273 / NM_001042492.3; = p.D2074H on NM_000267.3) | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as CD000988, COSV100646950; called by muse, varscan2
- NUP155 | c.3499C>T p.H1167Y (on ENST00000231498 / NM_153485.3; = p.H1108Y on NM_004298.4) | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs748884319; called by muse, mutect2, varscan2
- OR2AK2 | c.522T>G p.I174M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100824255; called by muse, mutect2
- OR52K1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 31/218 reads (14%) | catalogued as rs148398771, COSV56902951, COSV56904726; called by muse, mutect2, varscan2
- PAPPA2 | c.1837del p.R613Afs*24 | Frame Shift Del (DEL) | VAF 44/346 reads (13%) | catalogued as COSV62776739, COSV62782076; called by mutect2, pindel, varscan2
- PCDHGC3 | c.506T>C p.L169S | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1480639256; called by muse, mutect2, varscan2
- PGAP4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV66388532; called by muse, mutect2, varscan2
- PKHD1 | c.11216G>A p.R3739Q | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV100944809; called by muse, mutect2, varscan2
- PKHD1L1 | c.6928G>T p.E2310* | Nonsense Mutation (SNP) | VAF 25/390 reads (6%) | catalogued as COSV65752979; called by muse, mutect2
- PNMA3 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs782235238; called by muse, mutect2
- POLE | c.3818G>T p.R1273L | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs377324348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRC2C | c.7805G>T p.G2602V (on ENST00000367742; = p.G2600V on NM_015172.4) | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1192110704; called by muse, mutect2, varscan2
- RIPOR3 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50390146, COSV50390779; called by muse, mutect2, varscan2
- RSPH6A | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs776692589, COSV99679511; called by muse, mutect2
- RXYLT1 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748755896, COSV54167742; called by muse, mutect2
- RYR2 | c.3508G>T p.E1170* | Nonsense Mutation (SNP) | VAF 43/286 reads (15%) | catalogued as COSV100766976; called by muse, mutect2, varscan2
- SALL2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.724); catalogued as rs576329716, COSV58102538; called by muse, mutect2
- SIGLEC8 | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1000195859; called by muse, mutect2, varscan2
- SLC3A1 | c.1501-1G>A p.X501_splice | Splice Site (SNP) | VAF 30/337 reads (9%) | catalogued as COSV53225517; called by muse, mutect2
- TAS2R31 | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV66830218; called by muse, mutect2, varscan2
- TCP10L2 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1179434573; called by muse, mutect2, varscan2
- TGIF2LX | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 100/363 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52213346, COSV99033344; called by muse, mutect2, varscan2
- TMEM209 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100390432; called by muse, mutect2
- TNRC6B | c.4087C>G p.Q1363E (on ENST00000454349 / NM_001162501.2; = p.Q1253E on NM_015088.3) | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100109307; called by muse, mutect2
- TP53 | c.565dup p.A189Gfs*20 | Frame Shift Ins (INS) | VAF 54/317 reads (17%) | catalogued as COSV52945762; called by mutect2, pindel, varscan2
- TP53BP1 | c.3458G>A p.G1153E | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99780257; called by muse, mutect2, varscan2
- TTN | c.2761G>T p.G921* (on ENST00000591111; = p.G875* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 177/646 reads (27%) | catalogued as COSV60161643; called by muse, mutect2, varscan2
- TUSC1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63662221; called by muse, mutect2, varscan2
- UMOD | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV56777453; called by muse, mutect2, varscan2
- USP34 | c.9391G>A p.D3131N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV101277072; called by muse, mutect2, varscan2
- ZNF398 | c.1442G>T p.R481L (on ENST00000475153 / NM_170686.3; = p.R310L on NM_020781.4) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV104411232; called by muse, mutect2, varscan2
- ZNF441 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100777385; called by muse, mutect2
- ZNF814 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV71382211; called by muse, varscan2
- ABCC3 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- ABHD11 | c.625del p.V209Sfs*16 | Frame Shift Del (DEL) | VAF 86/577 reads (15%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO1 | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP11C | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BLMH | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- C20orf144 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); called by muse, mutect2
- CCDC175 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2
- CD9 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- CEP250 | c.2363G>T p.G788V | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, varscan2
- CFAP57 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- CHD2 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 17/536 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CLDN10 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- COL5A2 | c.2762G>T p.G921V | Missense Mutation (SNP) | VAF 71/549 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A5 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CST8 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CYFIP1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, mutect2
- DGKQ | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DST | c.6424G>T p.A2142S | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ECE1 | c.2062A>T p.K688* | Nonsense Mutation (SNP) | VAF 24/528 reads (5%) | called by muse, mutect2
- EEF1AKMT1 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPC1 | c.2297T>G p.V766G | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.099); called by muse, mutect2
- EPHA7 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERP27 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- FAM76A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FOXRED1 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- FRMD1 | c.498G>C p.L166F | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- G6PC2 | c.1036T>A p.L346I | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GBF1 | c.164-2A>T p.X55_splice | Splice Site (SNP) | VAF 18/150 reads (12%) | called by mutect2, varscan2
- GOLGA7B | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- GPR37 | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GRIP1 | c.2311C>T p.H771Y (on ENST00000359742 / NM_001379345.1; = p.H719Y on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HAP1 | c.1712A>T p.K571M (on ENST00000310778 / NM_001367460.1; = p.K519M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HSD11B1 | c.179A>T p.H60L | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQSEC1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ITGA6 | c.2056G>A p.G686R (on ENST00000442250; = p.G647R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ITPR1 | c.6179C>G p.S2060C (on ENST00000354582; = p.S2005C on NM_002222.7) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCP | c.790G>C p.E264Q (on ENST00000620378; = p.E321Q on NM_001366122.1) | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.718); called by muse, mutect2
- KLHL18 | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 16/616 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); called by muse, mutect2
- KRT85 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- LAMA5 | c.7148A>G p.D2383G | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- LRP1B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 32/419 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- LRTM2 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LY9 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 56/509 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MAP1LC3A | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- MTMR9 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC17 | c.13108G>T p.V4370L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH11 | c.3626C>A p.T1209K | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2
- MYT1L | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- NAV2 | c.5182C>G p.L1728V (on ENST00000396087 / NM_001244963.2; = p.L1672V on NM_145117.5) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCOA7 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLGN1 | c.2205G>T p.M735I | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2
- NLRC5 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 13/370 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- NRK | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OCA2 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.162); called by muse, mutect2
- OR10R2 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 67/506 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OR1C1 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR2M3 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2T8 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OXR1 | c.1318G>A p.D440N (on ENST00000442977 / NM_001198532.1; = p.D439N on NM_018002.3) | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- P2RX1 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2
- PEBP1 | c.517T>A p.W173R | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PLEKHG2 | c.2844G>T p.Q948H | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- POLR1A | c.3919G>C p.E1307Q | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.295); called by muse, mutect2
- PPP4R3C | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPP6R2 | c.2339C>T p.A780V (on ENST00000216061 / NM_001365836.1; = p.A753V on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- PRKACB | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2
- PRKD3 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | called by mutect2, varscan2
- PROX1 | c.2165C>G p.P722R | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPDC1 | c.299T>C p.L100P (on ENST00000375360 / NM_177995.3; = p.L152P on NM_152422.4) | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RNF38 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RTL1 | c.1877G>C p.R626T | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- S100A8 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- SEC16A | c.6884C>T p.S2295L | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SETD4 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SF3B1 | c.3158G>A p.R1053K | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.13); called by muse, mutect2
- SPTBN4 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TBC1D31 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- TFRC | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM171 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TMEM178B | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM9 | c.1534C>G p.R512G | Missense Mutation (SNP) | VAF 21/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRPS1 | c.2961T>A p.H987Q (on ENST00000220888 / NM_001330599.2; = p.H1000Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); called by muse, mutect2
- USH2A | c.10792A>T p.I3598F | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- WASHC2C | c.1836A>T p.K612N | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- WSCD2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZBTB7C | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF787 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ADRA2A | c.426C>T p.I142= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs1392919381, COSV54528085; called by muse, mutect2, varscan2
- CCDC168 | c.3084T>A p.G1028= | Silent (SNP) | VAF 19/152 reads (13%) | called by muse, mutect2, varscan2
- CHRNA1 | c.1281C>A p.I427= (on ENST00000261007 / NM_001039523.3; = p.I402= on NM_000079.4) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs756006671, COSV53684745; called by muse, mutect2
- CXXC1 | c.1539G>A p.T513= | Silent (SNP) | VAF 24/316 reads (8%) | catalogued as rs773144521; called by muse, mutect2
- DNAJB14 | c.426A>G p.A142= | Silent (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- ELP6 | c.129C>G p.L43= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- FER1L5 | c.3915C>T p.I1305= (on ENST00000623019; = p.I1278= on NM_001293083.2) | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as rs1298201795; called by muse, mutect2
- GABRA6 | c.1035C>A p.P345= | Silent (SNP) | VAF 49/285 reads (17%) | catalogued as rs767281233, COSV50881321; called by muse, mutect2, varscan2
- GABRB1 | c.252C>T p.L84= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs1286006170; called by muse, mutect2, varscan2
- GK3P | c.1641G>A p.R547= | Silent (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- GNB1 | c.855C>T p.L285= | Silent (SNP) | VAF 14/256 reads (5%) | catalogued as rs1557879564; called by muse, mutect2
- GPR63 | c.117C>T p.D39= | Silent (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- IGHG2 | c.435G>A p.V145= | Silent (SNP) | VAF 28/376 reads (7%) | catalogued as rs977885030; called by muse, mutect2
- KIAA2026 | c.4665G>T p.V1555= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- LRP12 | c.690C>T p.Y230= | Silent (SNP) | VAF 23/341 reads (7%) | called by muse, mutect2
- LY9 | c.330C>A p.T110= | Silent (SNP) | VAF 57/512 reads (11%) | called by muse, mutect2, varscan2
- MAML3 | c.690G>A p.Q230= | Silent (SNP) | VAF 43/348 reads (12%) | catalogued as rs369417459; called by muse, mutect2, varscan2
- NCAM1 | c.2013G>A p.L671= (on ENST00000316851 / NM_181351.5; = p.L661= on NM_000615.7) | Silent (SNP) | VAF 32/292 reads (11%) | catalogued as rs1394948400; called by muse, mutect2
- NSUN2 | c.7C>A p.R3= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- NUDT1 | c.360G>A p.E120= (on ENST00000397048 / NM_198952.1; = p.E97= on NM_002452.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- OR1J1 | c.273C>T p.A91= | Silent (SNP) | VAF 53/315 reads (17%) | catalogued as rs1279382037; called by muse, mutect2, varscan2
- OR7C2 | c.369C>T p.F123= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV50181858; called by muse, mutect2
- PDCD2 | c.39C>T p.F13= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- PLA2G4E | c.147C>G p.L49= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- PLEKHA4 | c.1749G>T p.P583= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV54364640; called by muse, mutect2, varscan2
- PLG | c.1101A>T p.P367= | Silent (SNP) | VAF 31/236 reads (13%) | called by muse, mutect2, varscan2
- PTGER2 | c.636C>T p.L212= | Silent (SNP) | VAF 29/412 reads (7%) | catalogued as rs1308911906, COSV55418609, COSV99817515; called by muse, mutect2
- RP1 | c.5415C>T p.L1805= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs1311244939, COSV55109911, COSV99609156; called by muse, mutect2, varscan2
- SCN5A | c.822C>T p.G274= | Silent (SNP) | VAF 23/343 reads (7%) | catalogued as COSV61133253; called by muse, mutect2
- SELENOT | c.48G>A p.R16= | Silent (SNP) | VAF 24/291 reads (8%) | catalogued as rs771895976; called by muse, mutect2
- SEPSECS | c.159C>G p.L53= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV57204830; called by muse, mutect2
- SFI1 | c.2106C>A p.A702= (on ENST00000400288 / NM_001007467.3; = p.A671= on NM_014775.4) | Silent (SNP) | VAF 42/251 reads (17%) | catalogued as rs1569452651; called by muse, mutect2, varscan2
- SLC4A3 | c.2985C>T p.L995= | Silent (SNP) | VAF 21/482 reads (4%) | catalogued as rs746896286; called by muse, mutect2
- SLC6A15 | c.483C>T p.I161= | Silent (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- SPATA3 | c.219A>G p.P73= | Silent (SNP) | VAF 40/411 reads (10%) | called by muse, mutect2
- SPTBN5 | c.10959C>G p.V3653= | Silent (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- SVIL | c.1938T>A p.G646= | Silent (SNP) | VAF 22/451 reads (5%) | called by muse, mutect2
- TCHHL1 | c.1848A>T p.G616= | Silent (SNP) | VAF 74/504 reads (15%) | called by muse, mutect2, varscan2
- TCOF1 | c.3159G>A p.K1053= (on ENST00000377797 / NM_001135243.1; = p.K976= on NM_000356.4) | Silent (SNP) | VAF 31/412 reads (8%) | catalogued as rs779690199; called by muse, mutect2
- TGIF2LX | c.390C>A p.A130= | Silent (SNP) | VAF 99/359 reads (28%) | catalogued as COSV52213328; called by muse, mutect2, varscan2
- TRIO | c.636A>G p.E212= | Silent (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- TXNDC15 | c.697C>T p.L233= | Silent (SNP) | VAF 40/366 reads (11%) | catalogued as COSV64379216; called by muse, varscan2
- VWF | c.6174C>A p.I2058= | Silent (SNP) | VAF 46/275 reads (17%) | called by muse, mutect2, varscan2
- ZNF862 | c.3509G>A p.*1170= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- ZSCAN21 | c.234C>T p.I78= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs374883018; called by muse, mutect2
- ACAN | c.*13G>A | 3'UTR (SNP) | VAF 24/322 reads (7%) | catalogued as rs1250490823; called by muse, mutect2
- ATG13 | c.790-807G>T | Intron (SNP) | VAF 66/334 reads (20%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3491G>A | Intron (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- CCT5 | c.*40A>G | 3'UTR (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- CENPC | c.1612+1410G>A | Intron (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- CLUAP1 | c.-39G>A | 5'UTR (SNP) | VAF 13/118 reads (11%) | catalogued as rs372807107; called by muse, mutect2, varscan2
- CPLANE1 | c.7957+320C>T | Intron (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- EHMT1 | c.3462-31C>T | Intron (SNP) | VAF 68/291 reads (23%) | called by muse, mutect2, varscan2
- FKBP6 | c.-128G>A | 5'UTR (SNP) | VAF 8/215 reads (4%) | catalogued as rs782810500; called by muse, mutect2
- FLT1 | c.-1C>A | 5'UTR (SNP) | VAF 43/242 reads (18%) | called by muse, mutect2, varscan2
- HGF | c.865+480C>G | Intron (SNP) | VAF 43/304 reads (14%) | called by muse, mutect2, varscan2
- KIT | c.-48G>A | 5'UTR (SNP) | VAF 12/108 reads (11%) | catalogued as rs1157869123, COSV99855645; called by muse, mutect2, varscan2
- LTBP3 | c.2893+34C>T | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- MAGEA4 | chrX:151912520 C>T | 5'Flank (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- MESP2 | c.-85G>T | 5'UTR (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- MTCL1 | c.3561+2421G>A | Intron (SNP) | VAF 36/354 reads (10%) | called by muse, mutect2
- MYPN | c.*238C>A | 3'UTR (SNP) | VAF 80/380 reads (21%) | called by muse, mutect2, varscan2
- PARVB | c.112+15417G>T | Intron (SNP) | VAF 25/160 reads (16%) | catalogued as rs1164589310; called by muse, mutect2, varscan2
- PHLDB1 | c.2737-586G>A | Intron (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.668-118C>A | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, varscan2
- PRKAA2 | c.-20C>G | 5'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, varscan2
- RACK1 | c.282-168C>T | Intron (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- RB1 | c.-96G>C | 5'UTR (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2
- RFXANK | c.271+30G>A | Intron (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- RPS6KA1 | c.*187C>T | 3'UTR (SNP) | VAF 33/372 reads (9%) | catalogued as rs776324092; called by muse, mutect2
